MMRF case MMRF_1985 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/1d503561-6913-4a0e-a1f1-615c6dc315a1

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 52 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 52.6 years (19,221 days); ISS stage: II; Days to last known disease status: 898 days (2.5 years); Days to last follow up: 898 days (2.5 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 2 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 175 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 3 days; Days to treatment end: 175 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 198 days; Days to treatment end: 252 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 253 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -15 (ECOG 1): M Protein 1.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.44 mg/dL; Immunoglobulin G 22.1 g/L; Immunoglobulin A 0.76 g/L; Immunoglobulin M 0.38 g/L; Beta 2 Microglobulin 1 µg/mL; Lactate Dehydrogenase 3.37 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 9.7 ×10⁹/L; Absolute Neutrophil 8.2 ×10⁹/L; Platelets 272 ×10⁹/L; Creatinine 43.3 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.18 mmol/L; Albumin 33 g/L; Total Protein 7 g/dL; Glucose 6.88 mmol/L; C-Reactive Protein 0.039 mg/dL.
- Day 92 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.05 mg/dL; Immunoglobulin G 2.71 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 3.18 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 5.6 g/dL; Glucose 5.78 mmol/L.
- Day 176 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.05 mg/dL; Immunoglobulin G 1.78 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 3.9 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 43.3 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 5.5 g/dL; Glucose 5.56 mmol/L.
- Day 282 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.71 mg/dL; Immunoglobulin G 4.61 g/L; Immunoglobulin A 0.85 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 244 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.4 mmol/L; Albumin 40 g/L; Total Protein 6 g/dL; Glucose 6.49 mmol/L.
- Day 373 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.45 mg/dL; Immunoglobulin G 7.78 g/L; Immunoglobulin A 1.15 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 2.12 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 45.1 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 6.33 mmol/L.
- Day 449 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.91 mg/dL; Immunoglobulin G 10.8 g/L; Immunoglobulin A 1.56 g/L; Immunoglobulin M 0.37 g/L; Lactate Dehydrogenase 2.27 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 6.22 mmol/L.
- Day 534 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.76 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 1.67 g/L; Immunoglobulin M 0.46 g/L; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 261 ×10⁹/L; Creatinine 52.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 6.49 mmol/L.
- Day 616 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.37 mg/dL; Immunoglobulin G 11.7 g/L; Immunoglobulin A 2.03 g/L; Immunoglobulin M 0.46 g/L; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 41.5 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 6.05 mmol/L.
- Day 730 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.17 mg/dL; Immunoglobulin G 10.8 g/L; Immunoglobulin A 2.08 g/L; Immunoglobulin M 0.4 g/L; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 239 ×10⁹/L; Creatinine 51.3 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 6.5 g/dL; Glucose 5.34 mmol/L.
- Day 813 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.22 mg/dL; Immunoglobulin G 12.4 g/L; Immunoglobulin A 2.37 g/L; Immunoglobulin M 0.46 g/L; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 7.1 g/dL; Glucose 5.06 mmol/L.
- Day 898 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.07 mg/dL; Immunoglobulin G 12.7 g/L; Immunoglobulin A 2.07 g/L; Immunoglobulin M 0.4 g/L; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 273 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 6.5 g/dL; Glucose 6.6 mmol/L.

Other clinical attributes
- Day -15: Weight: 118 kg; Height: 172 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1985_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -15 days.
- Sample MMRF_1985_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -15 days.
